HCMI case HCM-WCMC-0491-C16 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6e757d59-1eb2-4f38-b662-f3f543ba5844

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Year of birth: 1950; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, intestinal type: ICD-O-3 morphology code: 8144/3; ICD-10 code: C16.9; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Body of stomach; Classification of tumor: primary; Age at diagnosis: 66.0 years (24,110 days); AJCC staging edition: 8th; AJCC clinical stage: Stage IVB; AJCC pathologic T: T3; AJCC pathologic N: N2; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Tumor grade: G3; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Prior treatment: Yes; Sites of involvement: Liver; Tumor regression grade: 3.
   Pathology details: Lymphatic invasion present: Yes; Perineural invasion present: No; Vascular invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Leucovorin Calcium + Oxaliplatin; Treatment intent type: Neoadjuvant; Regimen or line of therapy: FOLFOX; Days to treatment start: 15 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Trastuzumab; Treatment intent type: Neoadjuvant; Days to treatment start: 15 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Leucovorin; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 234 days; Days to treatment end: 360 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 374 days (1.0 years); Days to treatment end: 619 days (1.7 years).
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Trastuzumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 374 days (1.0 years); Days to treatment end: 619 days (1.7 years).
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 730 days (2.0 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 962 days (2.6 years); Days to treatment end: 1,046 days (2.9 years).
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Trastuzumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 962 days (2.6 years); Days to treatment end: 1,128 days (3.1 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Leucovorin Calcium + Oxaliplatin; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Regimen or line of therapy: FOLFOX; Days to treatment start: 1,177 days (3.2 years); Days to treatment end: 1,182 days (3.2 years).
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 1,177 days (3.2 years); Days to treatment end: 1,182 days (3.2 years).
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Trastuzumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 1,177 days (3.2 years); Days to treatment end: 1,182 days (3.2 years).
   Recorded as not given: adjuvant Immunotherapy (Including Vaccines), for residual disease; neoadjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Liver; Days to progression: 0 days.
- Days to follow up: 1,577 days (4.3 years); Disease response: Complete Response; Progression or recurrence: No.
- Follow-up contact recording only the day: day 1,112.

Molecular and laboratory tests
- ERBB2 (IHC): Positive.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 91.6 kg; BMI: 26.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample HCM-WCMC-0491-C16-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen.
- Sample HCM-WCMC-0491-C16-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Cryopreserved; Passage count: 10.
